Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39T, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39T-01A (Primary Tumor).

[page 1 of 2]
	Yes	No

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1) THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

100-0-3

Carcinoma, papillary, follicular variant 8340/3

Site: thyroid, nrs C73.9 hw 9/14/11

TUMOR SITE:

Right lobe

HISTOLOGIC TYPE:

Papillary carcinoma, follicular variant, see note

TUMOR SIZE:

Greatest dimension 6 cm

FOCALITY:

Unifocal

LYMPH NODES:

All lymph nodes are negative for tumor (includes parts 1 and 3).

EXTENT OF INVASION

PRIMARY TUMOR:

Tumor >4 cm, limited to thyroid or with minimal extrathyroid extension

REGIONAL LYMPH NODES:

No regional lymph node metastasis

DISTANT METASTASIS:

Cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

2) LYMPH NODE, PRE-TRACHEAL (LYMPHADENECTOMY): TISSUE
INSUFFICIENT
FOR DIAGNOSIS.

[page 2 of 2]
3) NODAL TISSUE, RIGHT CENTRAL NECK (LYMPHADENECTOMY): TWO (2) BENIGN LYMPH NODES.

Note: The neoplasm shows varying degrees of atypia. While much of the neoplasm is composed of well-differentiated cells, focally, the presence of overlapping nuclei, nuclear pseudoinclusions, nuclear grooves, and nuclear atypia reach the diagnostic level of a follicular variant of papillary carcinoma. This case was shown at our

Source: NCI Genomic Data Commons file 2805b50c-ea4b-47ec-ab40-0d18e14558fd (TCGA-ET-A39T.CDD7A4EF-9901-4085-B897-975AE5E165D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).